Somatic mutation profile of tumor specimen TCGA-86-8076-01A (aliquot TCGA-86-8076-01A-31D-2238-08) from TCGA case TCGA-86-8076, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 42.7 years (15,605 days).
Specimen TCGA-86-8076-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f2bb436-47e8-4f0e-840f-13073e79be16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8076-10A (Blood Derived Normal), aliquot TCGA-86-8076-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56ee7c04-78c2-4484-bbff-7bca5056a4e3

The open-access MAF lists 67 somatic variants for this specimen: 50 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 15, Nonsense Mutation 3, RNA 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALDH18A1 | c.317A>G p.Q106R | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.955); catalogued as COSV64663841; called by muse, mutect2
- ALS2 | c.3358G>T p.G1120C | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51893815; called by muse, mutect2, varscan2
- ANKRD30A | c.910G>T p.D304Y (on ENST00000611781; = p.D248Y on NM_052997.2) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV64623341; called by muse, mutect2, varscan2
- ASGR2 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV54691865; called by muse, mutect2, varscan2
- BARHL2 | c.943T>A p.Y315N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64982211; called by muse, mutect2, varscan2
- CDT1 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV56350397; called by muse, mutect2
- CENPJ | c.2183G>C p.R728T | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV67884415; called by muse, mutect2, varscan2
- CHODL | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54735624; called by mutect2, varscan2
- CNTNAP2 | c.3177G>T p.K1059N | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV62267933; called by muse, mutect2, varscan2
- CTTNBP2 | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 22/168 reads (13%) | catalogued as COSV50494578; called by muse, varscan2
- DDX3X | c.1849G>A p.A617T (on ENST00000399959; = p.A618T on NM_001356.5) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs756197314, COSV67864651; called by muse, mutect2, varscan2
- EPB41 | c.653A>G p.D218G (on ENST00000343067 / NM_001166005.2; = p.D9G on NM_004437.4) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58055213; called by muse, mutect2
- FANCM | c.4210C>T p.H1404Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.188); catalogued as COSV57507589; called by muse, mutect2, varscan2
- GLYAT | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1282876168, COSV53540978; called by mutect2, varscan2
- GPAT2 | c.1416C>G p.F472L | Missense Mutation (SNP) | VAF 61/519 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1247323046, COSV64004060; called by muse, mutect2, varscan2
- GTF3C4 | c.2405-1G>C p.X802_splice | Splice Site (SNP) | VAF 13/153 reads (8%) | catalogued as rs1390299196, COSV64646318; called by muse, mutect2
- IGDCC4 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV61539608; called by muse, mutect2, varscan2
- INPP5J | c.2042G>A p.R681H (on ENST00000331075 / NM_001284285.2; = p.R313H on NM_001002837.2) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374379847; called by muse, varscan2
- KATNIP | c.4196G>A p.G1399D | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55193562; called by muse, mutect2, varscan2
- KIR2DL1 | c.244A>C p.K82Q | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52406873; called by muse, mutect2
- LAMA1 | c.3087G>T p.E1029D | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV67545290; called by muse, mutect2, varscan2
- LHCGR | c.737A>C p.Q246P | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV54304191; called by muse, mutect2, varscan2
- LILRA5 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as rs568171861, COSV56644835; called by muse, mutect2, varscan2
- LIN28A | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 19/264 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54263514; called by muse, mutect2
- MAGEB16 | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV67874759; called by muse, mutect2, varscan2
- MOCOS | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 18/145 reads (12%) | catalogued as COSV54347312; called by muse, mutect2
- NAPEPLD | c.560A>G p.H187R | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58524345; called by muse, mutect2, varscan2
- NFATC3 | c.3179C>T p.P1060L | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV52176695; called by muse, mutect2
- PEAK1 | c.3565G>A p.D1189N | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV56944749; called by muse, mutect2, varscan2
- PKD1L1 | c.8524G>A p.E2842K | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as rs1429348495, COSV51845466; called by muse, mutect2, varscan2
- PRDX2 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs746669088, COSV56878997; called by muse, mutect2, varscan2
- PTPN7 | c.769G>T p.D257Y (on ENST00000495688; = p.D296Y on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58315153; called by muse, mutect2
- PUS7L | c.1384C>G p.L462V | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as rs1052819782, COSV61263122; called by muse, mutect2, varscan2
- RC3H2 | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV61802876; called by muse, mutect2, varscan2
- RGS7 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 34/390 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.665); catalogued as COSV58563601; called by muse, mutect2
- RIT2 | c.83C>G p.A28G | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56310350; called by muse, mutect2, varscan2
- RPS6KA6 | c.325A>G p.K109E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53127930; called by muse, varscan2
- RYR2 | c.715G>T p.G239* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as COSV63696324, COSV63719437; called by muse, mutect2, varscan2
- SCN4A | c.4540G>A p.D1514N | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs374278037; called by muse, mutect2
- SLC40A1 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV53725322; called by muse, mutect2, varscan2
- SLITRK3 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.991); catalogued as COSV53854297; called by muse, mutect2
- SUGCT | c.104T>A p.M35K | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as COSV59358146; called by muse, mutect2, varscan2
- TCHHL1 | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as COSV64286610; called by muse, mutect2
- TLR6 | c.1731G>A p.M577I | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV67935884; called by muse, mutect2, varscan2
- TMEM130 | c.544G>T p.G182W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59561396; called by muse, mutect2, varscan2
- VPS18 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.691); catalogued as rs897174519, COSV55032583; called by muse, mutect2, varscan2
- ZNF10 | c.593A>T p.D198V | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV50215892; called by muse, mutect2
- ZNF695 | c.1540C>G p.H514D | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100377339, COSV60587823; called by muse, mutect2
- WASHC2C | c.3691A>G p.T1231A (on ENST00000336378; = p.T1210A on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- APEX2 | c.1263C>G p.L421= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV58193840; called by muse, mutect2, varscan2
- ARHGAP17 | c.2097G>A p.R699= (on ENST00000289968 / NM_001006634.3; = p.R621= on NM_018054.6) | Silent (SNP) | VAF 19/204 reads (9%) | catalogued as COSV51507346, COSV51512981; called by muse, mutect2, varscan2
- CHD1 | c.4950G>T p.T1650= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV52345370; called by muse, mutect2, varscan2
- DCC | c.3504A>T p.P1168= | Silent (SNP) | VAF 26/184 reads (14%) | catalogued as COSV71442092; called by muse, mutect2, varscan2
- HAVCR1 | c.489G>T p.T163= | Silent (SNP) | VAF 88/718 reads (12%) | called by mutect2, varscan2
- INHBA | c.816G>A p.K272= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV54225731; called by muse, mutect2
- MCM3AP | c.1773C>G p.S591= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as COSV52446482; called by muse, mutect2, varscan2
- NEK8 | c.1692G>A p.L564= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV52049335; called by muse, mutect2, varscan2
- PRPF4 | c.1449G>A p.P483= (on ENST00000374198 / NM_001322267.2; = p.P484= on NM_004697.5) | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as rs61737726; called by muse, mutect2
- PRRX1 | c.204G>C p.P68= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs759679693, COSV53419928; called by muse, mutect2, varscan2
- RGS7BP | c.351C>A p.I117= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs1426126328, COSV61837494; called by muse, mutect2
- STK19 | c.291C>G p.L97= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV61715346; called by muse, mutect2, varscan2
- TFAP2B | c.1200C>T p.L400= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV53832164; called by muse, mutect2, varscan2
- XKRX | c.1266T>C p.C422= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as COSV60709540; called by muse, mutect2, varscan2
- ZNF263 | c.1797A>G p.G599= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV54598327; called by muse, mutect2, varscan2
- FAM74A3 | n.343T>A | RNA (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- KIR3DX1 | n.1029G>T | RNA (SNP) | VAF 7/64 reads (11%) | catalogued as rs1481402691; called by muse, mutect2, varscan2
